Somatic mutation profile of tumor specimen TCGA-2A-A8VV-01A (aliquot TCGA-2A-A8VV-01A-11D-A377-08) from TCGA case TCGA-2A-A8VV, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 52.2 years (19,065 days).
Specimen TCGA-2A-A8VV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec47ff9f-0639-4e3a-84d0-ff1403fb12ab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2A-A8VV-10A (Blood Derived Normal), aliquot TCGA-2A-A8VV-10A-01D-A37A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b7787adf-f06d-4ea7-8298-a1f1b31ba414

The open-access MAF lists 22 somatic variants for this specimen: 17 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 4, Splice Site 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGAP4 | c.1328C>T p.A443V | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs782392263, COSV101432675; called by muse, mutect2, varscan2
- ATP8B2 | c.609-1G>A p.X203_splice (on ENST00000672630; = p.X170_splice on NM_001005855.2) | Splice Site (SNP) | VAF 3/11 reads (27%) | catalogued as COSV100528048; called by muse, mutect2
- BIVM-ERCC5 | c.2853A>T p.R951S | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.005); catalogued as COSV100863808; called by mutect2, varscan2
- CDH23 | c.4913A>G p.H1638R | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV99821710; called by muse, mutect2
- CFAP65 | c.1991C>T p.P664L | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.112); catalogued as COSV100445308; called by muse, mutect2, varscan2
- DNAJC7 | c.289C>T p.R97W | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as COSV100348138, COSV57270952; called by muse, mutect2
- MYO7A | c.1627A>T p.N543Y | Missense Mutation (SNP) | VAF 9/174 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.408); catalogued as COSV101289169; called by muse, mutect2
- OR2G2 | c.902A>T p.K301I | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV100189787; called by muse, mutect2
- OR8G5 | c.566G>C p.C189S | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.469); catalogued as rs1199229262, COSV100422501; called by muse, mutect2, varscan2
- PKHD1L1 | c.4003A>C p.M1335L | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV101006342; called by muse, mutect2, varscan2
- PTPRD | c.4340G>A p.R1447Q | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.32); catalogued as rs752508898, COSV100645251; called by muse, mutect2, varscan2
- SAMD9 | c.3620C>A p.T1207K | Missense Mutation (SNP) | VAF 7/137 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.076); catalogued as COSV66074301; called by muse, mutect2
- SLC17A6 | c.615G>A p.W205* | Nonsense Mutation (SNP) | VAF 3/42 reads (7%) | catalogued as COSV99581681; called by muse, mutect2
- SYNE1 | c.12863G>A p.R4288K (on ENST00000367255 / NM_182961.4; = p.R4217K on NM_033071.3) | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV99568150; called by muse, mutect2, varscan2
- TACSTD2 | c.342C>A p.F114L | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1326904511, COSV100973753; called by muse, mutect2, varscan2
- TUBGCP3 | c.184C>T p.L62F | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs1193305045, COSV99996970; called by muse, mutect2
- ZNF568 | c.907G>C p.E303Q | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100451315, COSV61743061; called by muse, mutect2
- MUC17 | c.7656C>A p.I2552= | Silent (SNP) | VAF 74/281 reads (26%) | catalogued as COSV100073837; called by muse, mutect2, varscan2
- OR8I2 | c.720C>T p.C240= | Silent (SNP) | VAF 48/99 reads (48%) | catalogued as rs141691557, COSV100135786; called by muse, mutect2, varscan2
- ZNF518B | c.2133C>T p.N711= | Silent (SNP) | VAF 36/100 reads (36%) | catalogued as rs766040632, COSV58722070, COSV58722183; called by muse, mutect2, varscan2
- ZNF652 | c.438T>A p.V146= | Silent (SNP) | VAF 6/97 reads (6%) | called by muse, mutect2
- GRM8 | c.727+48380C>T | Intron (SNP) | VAF 8/82 reads (10%) | catalogued as rs1414578610, COSV58808115; called by muse, mutect2, varscan2
